Somatic mutation profile of tumor specimen HCM-BROD-0642-C43-06A (aliquot HCM-BROD-0642-C43-06A-11D-A85K-36) from HCMI case HCM-BROD-0642-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.0 years (19,715 days).
Specimen HCM-BROD-0642-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b21c294-c000-4942-84dc-37b603491acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0642-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0642-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d44f937-ba22-46db-96b5-f1e5b609b106

The open-access MAF lists 881 somatic variants for this specimen: 572 protein-altering or splice-affecting, 271 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 522, Silent 271, Nonsense Mutation 34, Intron 23, Splice Region 9, Splice Site 5, 3'Flank 4, RNA 4, 5'Flank 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1.

Variants (750 of 881; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD4B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 111/194 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV68328045; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 228/340 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- PDE6B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs398123299, CM149250; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 162/176 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3011C>T p.S1004L | Missense Mutation (SNP) | VAF 174/396 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99713399; called by muse, mutect2, varscan2
- ABCC12 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912507; called by muse, mutect2, varscan2
- ACSF3 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1247248093; called by muse, mutect2, varscan2
- ADAM18 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55852466; called by muse, mutect2, varscan2
- ADAM7 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 154/333 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538725; called by muse, mutect2, varscan2
- ADAM7 | c.1696C>T p.L566F | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs1420495781; called by muse, mutect2, varscan2
- ADAMTS20 | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 133/149 reads (89%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as rs779915911; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 148/321 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV58443126; called by muse, mutect2, varscan2
- ADGRL3 | c.1100G>A p.G367E (on ENST00000506720 / NM_001322402.2; = p.G299E on NM_015236.6) | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101547265, COSV72265789; called by muse, mutect2, varscan2
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- ADRA1D | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 244/556 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.42); catalogued as rs1305160550; called by muse, mutect2, varscan2
- AGMO | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61108972; called by muse, mutect2, varscan2
- ALKBH8 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 89/116 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760087113; called by muse, mutect2, varscan2
- ALPK2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 99/388 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as rs1365235325; called by muse, mutect2
- AMER1 | c.2820G>T p.W940C | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100365966, COSV57654932; called by muse, mutect2, varscan2
- AMER1 | c.2819G>T p.W940L | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV57666543; called by muse, mutect2, varscan2
- APCS | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201641715; called by muse, mutect2, varscan2
- APOB | c.12034G>A p.D4012N | Missense Mutation (SNP) | VAF 257/384 reads (67%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs781252339; called by muse, mutect2, varscan2
- ARSF | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 168/256 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV63839940; called by muse, mutect2, varscan2
- ASB15 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1272694122; called by muse, mutect2, varscan2
- ATP12A | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 169/249 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.484); catalogued as rs1346442488; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 236/470 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.955); catalogued as rs774903056, COSV59478969; called by muse, mutect2
- ATXN7L2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 417/581 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100149765; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2860C>T p.R954W | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs137877463; called by muse, mutect2, varscan2
- CARD11 | c.3079C>T p.R1027* | Nonsense Mutation (SNP) | VAF 202/436 reads (46%) | catalogued as COSV67797950; called by muse, mutect2
- CATSPERB | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 73/204 reads (36%) | catalogued as rs779893104, COSV56422429, COSV99831126; called by muse, mutect2, varscan2
- CBLL2 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs1003703661, COSV60369345; called by muse, mutect2, varscan2
- CBX4 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 336/362 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1416178193; called by muse, varscan2
- CCDC141 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV69467420; called by muse, mutect2, varscan2
- CD180 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 208/227 reads (92%) | catalogued as rs1181496324, COSV56516941; called by muse, mutect2, varscan2
- CD1A | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 348/480 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV56862226; called by muse, mutect2, varscan2
- CDCP1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 232/417 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs754165008, COSV56103701; called by muse, mutect2, varscan2
- CDH15 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 266/442 reads (60%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.943); catalogued as rs763753067, COSV57021649; called by muse, mutect2, varscan2
- CDKL3 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 120/131 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs950220793; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 353/398 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CDYL2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 100/166 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV101629513; called by muse, mutect2, varscan2
- CEACAM8 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.1); catalogued as COSV54991875; called by muse, mutect2, varscan2
- CES5A | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 110/424 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs376873682; called by muse, mutect2
- CFAP47 | c.8684C>T p.P2895L | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.268); catalogued as COSV66216742; called by muse, mutect2, varscan2
- CHRNA6 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.842); catalogued as rs777615925, COSV52378862; called by muse, mutect2, varscan2
- CNTN5 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV54346954, COSV54361372; called by muse, mutect2
- CNTNAP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 140/305 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777035367, COSV100663349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1899G>A p.E633= | Splice Region (SNP) | VAF 131/237 reads (55%) | catalogued as rs1186277979; called by muse, mutect2, varscan2
- CNTNAP4 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs772774812; called by muse, mutect2, varscan2
- COL19A1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 165/327 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1325736401; called by muse, mutect2, varscan2
- COL4A4 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs1286834392; called by muse, mutect2, varscan2
- COL4A5 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 297/497 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV60372025; called by muse, mutect2, varscan2
- COL4A6 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 182/346 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57860173; called by muse, mutect2, varscan2
- COL6A3 | c.4484C>T p.S1495F | Missense Mutation (SNP) | VAF 116/466 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV55080970; called by muse, mutect2, varscan2
- CPAMD8 | c.2144G>A p.R715Q (on ENST00000651564; = p.R668Q on NM_015692.5) | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs377267185; called by muse, varscan2
- CRB1 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1435210193, COSV66329814; called by muse, mutect2, varscan2
- CRISP2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as COSV59255739, COSV59256565; called by muse, mutect2, varscan2
- CROCC2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as rs1254764947; called by muse, mutect2, varscan2
- CWH43 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs772880873; called by muse, mutect2, varscan2
- CYP2C9 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 126/141 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1336467386; called by muse, mutect2, varscan2
- DAW1 | c.881A>T p.K294I | Missense Mutation (SNP) | VAF 133/194 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV59366102; called by muse, mutect2, varscan2
- DCHS2 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV59725390; called by muse, mutect2, varscan2
- DEFB121 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV66236013; called by muse, mutect2, varscan2
- DNAH12 | c.3301C>T p.R1101* (on ENST00000351747; = p.R1124* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 90/234 reads (38%) | catalogued as rs1377761886; called by muse, mutect2, varscan2
- DNAH14 | c.9113G>A p.G3038E (on ENST00000445597; = p.G3802E on NM_001367479.1) | Missense Mutation (SNP) | VAF 139/186 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1334446947; called by muse, varscan2
- DNAH7 | c.4310G>A p.R1437Q | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547682335; called by muse, mutect2, varscan2
- DNALI1 | c.185C>T p.P62L (on ENST00000296218; = p.P40L on NM_003462.5) | Missense Mutation (SNP) | VAF 336/468 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs559111896; called by muse, mutect2, varscan2
- DRG2 | c.1094A>C p.*365Sext*51 | Nonstop Mutation (SNP) | VAF 152/168 reads (90%) | catalogued as COSV52753678; called by muse, mutect2, varscan2
- DSC3 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs866687286, COSV100844559; called by muse, mutect2, varscan2
- DSCAM | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 134/224 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs765431927, COSV68022737; called by muse, mutect2, varscan2
- DSG1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 123/214 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as COSV57137308; called by muse, mutect2, varscan2
- DZANK1 | c.1645G>A p.D549N (on ENST00000262547 / NM_001099407.1; = p.D356N on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/312 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs560238158; called by muse, mutect2, varscan2
- EGFL6 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100789876, COSV63633565; called by muse, mutect2, varscan2
- ELK3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 208/227 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1388786729, COSV99957627; called by muse, mutect2, varscan2
- ELOA3C | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 130/3160 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV55303219; called by muse, mutect2
- ENAM | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs752376600, COSV101252837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPEP | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs868690232, COSV54453439; called by muse, mutect2, varscan2
- EPHA6 | c.2575-1G>A p.X859_splice (on ENST00000389672 / NM_001080448.3; = p.X251_splice on NM_173655.4) | Splice Site (SNP) | VAF 117/206 reads (57%) | catalogued as COSV67585238; called by muse, mutect2, varscan2
- EPHB1 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV101212774, COSV67660470; called by muse, mutect2, varscan2
- FAM117B | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57417833; called by muse, mutect2, varscan2
- FAT3 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 113/140 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99971681; called by muse, mutect2, varscan2
- FAT4 | c.12860G>A p.G4287E | Missense Mutation (SNP) | VAF 104/188 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58685287; called by muse, mutect2, varscan2
- FBN2 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 189/217 reads (87%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs149691045; called by muse, mutect2, varscan2
- FER1L5 | c.3207G>A p.W1069* (on ENST00000623019; = p.W1042* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 305/453 reads (67%) | catalogued as COSV101208862; called by muse, mutect2, varscan2
- FEZF1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 253/544 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs534580940, COSV100484547; called by muse, mutect2, varscan2
- FLG | c.3725C>T p.S1242F | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV64242619, COSV64243917; called by muse, mutect2, varscan2
- FMN2 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 306/409 reads (75%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.105); catalogued as COSV60440194; called by muse, mutect2, varscan2
- FMO1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 100/418 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61447799; called by muse, mutect2, varscan2
- FNDC1 | c.4292G>A p.G1431E | Missense Mutation (SNP) | VAF 247/487 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51943734; called by muse, mutect2, varscan2
- FPGT | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV100907611; called by muse, mutect2, varscan2
- FPR2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV60671857; called by muse, mutect2, varscan2
- FREM3 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs921710271; called by muse, mutect2, varscan2
- FRMPD3 | c.4340C>T p.P1447L | Missense Mutation (SNP) | VAF 233/401 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs1288508797; called by muse, mutect2, varscan2
- FSHR | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103069; called by muse, mutect2, varscan2
- GABRB2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 144/150 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs920578043; called by muse, mutect2, varscan2
- GABRG1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.119); catalogued as rs1182767573; called by muse, mutect2, varscan2
- GABRQ | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 274/454 reads (60%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.401); catalogued as rs138966264, COSV64780848; called by muse, mutect2, varscan2
- GAP43 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 239/409 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1465340469; called by muse, mutect2, varscan2
- GBA3 | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | catalogued as COSV72438405; called by muse, mutect2, varscan2
- GC | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1243573769, COSV56736346; called by muse, mutect2, varscan2
- GDA | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 118/125 reads (94%) | catalogued as COSV52996277, COSV99429177; called by muse, mutect2, varscan2
- GDPD3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 108/319 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as rs751057196; called by muse, mutect2, varscan2
- GLYATL2 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 174/202 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV54849840; called by muse, mutect2, varscan2
- GPR31 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 25/499 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.338); catalogued as rs756916147, COSV64761079; called by muse, mutect2
- GSAP | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200710818; called by muse, mutect2, varscan2
- GTSF1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 150/168 reads (89%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs777098460, COSV59938543; called by muse, mutect2, varscan2
- GYPA | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as rs1233992553, COSV51619643; called by muse, mutect2, varscan2
- H1-4 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 229/447 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762441962, COSV56803632; called by muse, mutect2, varscan2
- HERC1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 283/395 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs780509864; called by muse, mutect2, varscan2
- HNRNPA1P48 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 156/275 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1289906791; called by muse, mutect2, varscan2
- HTR3E | c.776G>C p.G259A (on ENST00000415389 / NM_001256613.1; = p.G274A on NM_182589.2) | Missense Mutation (SNP) | VAF 176/284 reads (62%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); catalogued as COSV58949369; called by muse, mutect2, varscan2
- HUWE1 | c.11968C>T p.R3990C | Missense Mutation (SNP) | VAF 188/325 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53345595; called by muse, mutect2, varscan2
- IFT122 | c.1393C>T p.R465W (on ENST00000348417 / NM_052989.3; = p.R406W on NM_018262.4) | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs199672717; called by muse, varscan2
- IGKV1D-8 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 62/278 reads (22%) | catalogued as rs532002660; called by muse, varscan2
- INSL6 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 184/197 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs757105790, COSV67563043; called by muse, mutect2, varscan2
- INTS4 | c.1580G>A p.S527N | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1360732683; called by muse, mutect2, varscan2
- JAM2 | c.822G>A p.Q274= | Splice Region (SNP) | VAF 42/115 reads (37%) | catalogued as rs1568922321; called by muse, mutect2, varscan2
- KCNH7 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100035243, COSV59793528; called by muse, mutect2, varscan2
- KLK3 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 76/245 reads (31%) | catalogued as COSV100386045; called by muse, mutect2, varscan2
- KRTDAP | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 199/322 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs1046945251; called by muse, mutect2, varscan2
- L1CAM | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 119/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151703; called by muse, mutect2, varscan2
- LARP1B | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 107/196 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs753246881; called by muse, mutect2, varscan2
- LAT | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 121/438 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV57956799; called by muse, mutect2
- LCT | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 268/400 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51549649; called by muse, mutect2, varscan2
- LRGUK | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV53645130; called by muse, mutect2, varscan2
- LRP12 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 153/335 reads (46%) | catalogued as rs746567684, COSV99408078; called by muse, mutect2, varscan2
- LRRC36 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as rs1192987124; called by muse, varscan2
- LYPD8 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 84/413 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.402); catalogued as COSV74038953; called by muse, mutect2, varscan2
- LYSMD1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340255999; called by muse, mutect2, varscan2
- MAP3K13 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs749369724; called by muse, mutect2, varscan2
- MARCO | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as rs765014059, COSV100503536, COSV59053740; called by muse, mutect2, varscan2
- MASP1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.668); catalogued as COSV51462236; called by muse, mutect2, varscan2
- MAST2 | c.3414G>A p.W1138* | Nonsense Mutation (SNP) | VAF 171/231 reads (74%) | catalogued as rs1403728611; called by muse, mutect2, varscan2
- ME1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100866702; called by muse, mutect2, varscan2
- MEGF8 | c.5083C>T p.H1695Y (on ENST00000251268 / NM_001271938.2; = p.H1628Y on NM_001410.3) | Missense Mutation (SNP) | VAF 245/424 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1437438277; called by muse, mutect2, varscan2
- MEST | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 189/447 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV56229458; called by muse, mutect2, varscan2
- MIDEAS | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 282/522 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867908288; called by muse, mutect2, varscan2
- MMP16 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 182/391 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs368200792; called by muse, mutect2, varscan2
- MMP9 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 190/418 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64885894; called by muse, mutect2, varscan2
- MMRN1 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53335214; called by muse, mutect2, varscan2
- MOGAT2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs919207766; called by muse, mutect2
- MRAP2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs368589399, CM136933; called by muse, mutect2, varscan2
- MSLN | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 88/309 reads (28%) | catalogued as rs1389452450; called by muse, mutect2, varscan2
- MSN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 147/262 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs886913201, COSV64305543; called by muse, mutect2, varscan2
- MUC12 | c.12260C>T p.P4087L (on ENST00000379442; = p.P3944L on NM_001164462.1) | Missense Mutation (SNP) | VAF 164/1518 reads (11%) | SIFT deleterious (0); catalogued as COSV65207366; called by muse, mutect2, varscan2
- MUC16 | c.42040C>T p.H14014Y | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.93); catalogued as rs765270798, COSV101109359, COSV101110067; called by muse, mutect2, varscan2
- MUC16 | c.17764G>A p.E5922K | Missense Mutation (SNP) | VAF 160/258 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV67451764; called by muse, mutect2, varscan2
- MUC16 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV67454362; called by muse, mutect2, varscan2
- MUC17 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 217/489 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV60281150; called by muse, mutect2, varscan2
- MYD88 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs893672462; called by muse, varscan2
- MYH15 | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 177/323 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs773055758, COSV56310970; called by muse, mutect2, varscan2
- MYH9 | c.5675C>T p.S1892F | Missense Mutation (SNP) | VAF 436/798 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs1450702017; called by muse, varscan2
- MYO5C | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs943150513, COSV55906769; called by muse, mutect2, varscan2
- MYT1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 343/760 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as rs377464140; called by muse, varscan2
- N4BP2L2 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 157/239 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV57227820; called by muse, mutect2, varscan2
- NAV1 | c.5074C>T p.R1692C | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55214249; called by muse, mutect2, varscan2
- NCALD | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 144/287 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1212404446, COSV99637596; called by muse, mutect2, varscan2
- NEFL | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55337980; called by muse, mutect2, varscan2
- NLRP10 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60781378; called by muse, mutect2, varscan2
- NLRP10 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 220/267 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs867689286; called by muse, mutect2, varscan2
- NME8 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 175/326 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV52250387; called by muse, mutect2, varscan2
- NOTCH3 | c.3682G>A p.G1228R | Missense Mutation (SNP) | VAF 246/387 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs142798406; called by muse, mutect2, varscan2
- NOXA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 225/239 reads (94%) | catalogued as rs113228211; called by muse, mutect2, varscan2
- NPDC1 | c.387C>T p.A129= | Splice Region (SNP) | VAF 213/353 reads (60%) | catalogued as rs1322667400; called by muse, mutect2, varscan2
- NRP2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs753461978, COSV55929465, COSV55935149; called by muse, mutect2, varscan2
- NUAK2 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 274/381 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); catalogued as COSV65681517; called by muse, mutect2, varscan2
- NWD1 | c.4526C>T p.S1509L | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV60342636; called by muse, mutect2, varscan2
- NYAP2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 257/391 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as rs1283487046, COSV99797152; called by muse, mutect2, varscan2
- OR11H1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 94/730 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1376708696; called by muse, varscan2
- OR11H2 | c.487C>T p.P163S (on ENST00000556246; = p.P174S on NM_001197287.1) | Missense Mutation (SNP) | VAF 184/735 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); catalogued as rs760193968; called by muse, mutect2, varscan2
- OR13C2 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 155/172 reads (90%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs75012681, COSV73377741; called by muse, mutect2, varscan2
- OR13C9 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 100/108 reads (93%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV52243229; called by muse, mutect2, varscan2
- OR1M1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 110/330 reads (33%) | catalogued as rs761691660; called by muse, mutect2, varscan2
- OR2J3 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 209/470 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1458090557, COSV65849602; called by muse, mutect2, varscan2
- OR2T1 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 459/615 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs752461348; called by muse, mutect2, varscan2
- OR2T33 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 136/286 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs756717060, COSV58814950; called by muse, mutect2, varscan2
- OR2T8 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs764332590, COSV100177967; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR51V1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 70/93 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV58315835; called by muse, mutect2, varscan2
- OR52B6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs367796432; called by muse, mutect2
- PAX9 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 193/375 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1206808645; called by muse, mutect2
- PCDH15 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 187/207 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937306164; called by muse, mutect2, varscan2
- PCDHA13 | c.762C>A p.N254K | Missense Mutation (SNP) | VAF 165/181 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV56506833; called by muse, mutect2, varscan2
- PCLO | c.13982C>T p.S4661F | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100429088; called by muse, mutect2, varscan2
- PCLO | c.10930G>A p.E3644K | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61615258; called by muse, mutect2, varscan2
- PCLO | c.8060C>T p.P2687L | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100436257; called by muse, mutect2, varscan2
- PCLO | c.6673G>A p.E2225K | Missense Mutation (SNP) | VAF 122/267 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61665165; called by muse, mutect2, varscan2
- PCOLCE2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 187/342 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1281908625, COSV56001100, COSV99930424; called by muse, mutect2, varscan2
- PHKB | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 175/300 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs555108367, COSV54519213; called by muse, mutect2, varscan2
- PKD2 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763671263; called by mutect2, varscan2
- PLEC | c.1747G>T p.D583Y (on ENST00000322810 / NM_201380.4; = p.D473Y on NM_000445.5) | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59648106; called by muse, mutect2
- PMIS2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 180/330 reads (55%) | SIFT tolerated, low confidence (0.08); catalogued as rs1022717243; called by muse, varscan2
- POTEF | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 317/487 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1558878615, COSV62540473; called by muse, mutect2, varscan2
- PPFIA2 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 127/244 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV61025332; called by muse, mutect2, varscan2
- PPP1R3A | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 163/363 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs62001880, COSV99492473; called by muse, mutect2, varscan2
- PRAMEF11 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 413/623 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs1406291079, COSV70819695; called by muse, mutect2, varscan2
- PRB3 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 195/263 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs764834666, COSV54387759; called by muse, mutect2, varscan2
- PRKG1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 169/182 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV64766173; called by muse, mutect2, varscan2
- PRORP | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51623178; called by muse, mutect2, varscan2
- PRSS58 | c.576+1G>A p.X192_splice | Splice Site (SNP) | VAF 117/252 reads (46%) | catalogued as rs1335781612, COSV101616127; called by muse, mutect2, varscan2
- PSG3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.52); catalogued as COSV100548877; called by muse, mutect2, varscan2
- PSG8 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs142736244; called by muse, mutect2, varscan2
- PTPRD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 103/114 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61932719; called by muse, mutect2, varscan2
- PTPRK | c.1578C>T p.I526= | Splice Region (SNP) | VAF 90/208 reads (43%) | catalogued as rs749452894, COSV63891671; called by muse, mutect2, varscan2
- PTPRN2 | c.1723G>A p.V575I | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV67061169; called by muse, mutect2, varscan2
- PTPRQ | c.3025C>T p.L1009F (on ENST00000616559; = p.L967F on NM_001145026.2) | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57058573; called by muse, mutect2, varscan2
- PWWP3B | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61801797; called by muse, mutect2, varscan2
- RAD9A | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.111); catalogued as rs1243441285; called by muse, varscan2
- RAPH1 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 117/473 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as COSV99863502; called by muse, mutect2, varscan2
- RBM20 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 268/286 reads (94%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as rs1387833836; called by muse, mutect2, varscan2
- RFPL4B | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 187/409 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769985727, COSV101480733, COSV71437071; called by muse, mutect2, varscan2
- RGPD4 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs780907507, COSV100736346, COSV61747255; called by muse, varscan2
- RGPD4 | c.3748G>A p.D1250N | Missense Mutation (SNP) | VAF 278/413 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1246903240, COSV61744713; called by muse, varscan2
- RND1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 164/181 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370916812, COSV59045178; called by muse, mutect2, varscan2
- RORC | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59091823; called by muse, mutect2, varscan2
- ROS1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 191/427 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs756348072, COSV63859785; called by muse, mutect2, varscan2
- RP1L1 | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as rs1249088401; called by muse, varscan2
- RPS6KL1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 175/424 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1462377523; called by muse, mutect2, varscan2
- RTP1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 154/468 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as COSV100398704; called by muse, mutect2, varscan2
- RYR2 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 290/415 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs372569289, COSV104419366; called by muse, mutect2, varscan2
- SCMH1 | c.766C>T p.P256S (on ENST00000326197 / NM_001031694.2; = p.P209S on NM_012236.4) | Missense Mutation (SNP) | VAF 193/289 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs780187552; called by muse, mutect2, varscan2
- SCN1A | c.2045G>A p.G682E (on ENST00000303395 / NM_001202435.3; = p.G671E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV100320394, COSV57674580; called by muse, mutect2, varscan2
- SCN7A | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 134/231 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV69270889; called by muse, mutect2, varscan2
- SDK1 | c.6485G>A p.G2162D | Missense Mutation (SNP) | VAF 265/603 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV67381918; called by muse, mutect2, varscan2
- SEL1L2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 114/274 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs762935961; called by muse, mutect2, varscan2
- SERPINB10 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 208/366 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs865940322, COSV53072764; called by muse, mutect2
- SERPINB3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 132/225 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV99379684; called by muse, mutect2, varscan2
- SETX | c.3967C>T p.R1323* | Nonsense Mutation (SNP) | VAF 145/161 reads (90%) | catalogued as rs200437136, COSV56386610; called by muse, mutect2, varscan2
- SHANK1 | c.2673C>T p.I891= | Splice Region (SNP) | VAF 117/207 reads (57%) | catalogued as rs761139887, COSV53256432; called by muse, mutect2, varscan2
- SHOC1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 90/98 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762528572; called by muse, mutect2, varscan2
- SHROOM3 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs778673286, COSV99934048; called by muse, mutect2, varscan2
- SIGLEC7 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 154/480 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58315902; called by muse, mutect2, varscan2
- SLC35F4 | c.1432G>A p.E478K (on ENST00000339762 / NM_001352015.2; = p.E442K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV100334256; called by muse, mutect2, varscan2
- SLC38A11 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 121/168 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58052679; called by muse, mutect2, varscan2
- SLC44A5 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 182/254 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as rs768778680, COSV100902601, COSV63763805; called by muse, varscan2
- SLC5A9 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 211/278 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs1232655073, COSV52581751; called by muse, mutect2, varscan2
- SLC9C2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 139/222 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1010780200; called by muse, mutect2, varscan2
- SLIT2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs139887501; called by muse, mutect2, varscan2
- SMARCA4 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 127/411 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as rs1270509173, COSV60807966; called by muse, mutect2, varscan2
- SNX27 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 196/276 reads (71%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.903); catalogued as COSV64327156; called by muse, mutect2, varscan2
- SORCS1 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 126/142 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99548050; called by muse, mutect2, varscan2
- SORL1 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52754570; called by muse, mutect2
- SORL1 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 124/180 reads (69%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV52762812; called by muse, mutect2, varscan2
- SPANXD | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 226/382 reads (59%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.708); catalogued as COSV65153267; called by muse, mutect2, varscan2
- SPTA1 | c.5710G>A p.E1904K | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV63760561; called by muse, mutect2, varscan2
- SPTA1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 252/338 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as rs779418877, COSV63748977; called by muse, varscan2
- STAB1 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.522); catalogued as rs774375422; called by muse, mutect2, varscan2
- SULT1E1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56946766; called by muse, mutect2, varscan2
- SVIL | c.3788C>T p.S1263L (on ENST00000355867 / NM_021738.3; = p.S837L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs149199305, COSV63441273; called by muse, mutect2
- SYNE1 | c.1552C>T p.L518F (on ENST00000367255 / NM_182961.4; = p.L525F on NM_033071.3) | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV54906937; called by muse, mutect2, varscan2
- SYTL4 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV52172929; called by muse, mutect2, varscan2
- TAFA1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs1359732390, COSV72038948; called by muse, mutect2, varscan2
- TAFA2 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 138/262 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1295895439; called by muse, mutect2, varscan2
- TBX5 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 241/260 reads (93%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as rs781143449; called by muse, mutect2, varscan2
- TENM4 | c.7159G>A p.E2387K | Missense Mutation (SNP) | VAF 160/201 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV53630425; called by muse, mutect2, varscan2
- TEX13A | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 108/289 reads (37%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.992); catalogued as rs782324559; called by muse, mutect2, varscan2
- TGM2 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV100821450; called by muse, mutect2, varscan2
- THSD1 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 267/424 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.057); catalogued as rs376549270; called by muse, mutect2, varscan2
- TLDC2 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 150/309 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs202081152, COSV54113366; called by muse, mutect2, varscan2
- TLL1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs150728189, COSV50304665; called by muse, mutect2, varscan2
- TLR2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52605719; called by muse, mutect2, varscan2
- TLR3 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750961101; called by muse, mutect2, varscan2
- TLR5 | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 266/366 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV60557771; called by muse, mutect2, varscan2
- TMEM229B | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 232/449 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV62538335; called by muse, mutect2, varscan2
- TMEM272 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 203/299 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.196); catalogued as rs1470195167; called by muse, mutect2, varscan2
- TMEM43 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.119); catalogued as rs765816901, CM1313003, COSV100044356, COSV60145153; called by muse, mutect2, varscan2
- TMPRSS7 | c.2453G>A p.R818Q (on ENST00000452346; = p.R692Q on NM_001042575.2) | Missense Mutation (SNP) | VAF 199/341 reads (58%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs774677609, COSV69982809; called by muse, mutect2, varscan2
- TNN | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53437224; called by muse, mutect2, varscan2
- TOPAZ1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as rs1239988482; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2
- TRIM25 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 203/221 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs533748559; called by muse, mutect2, varscan2
- TSHR | c.390C>T p.F130= | Splice Region (SNP) | VAF 156/295 reads (53%) | catalogued as COSV53327314; called by muse, mutect2, varscan2
- TTLL5 | c.3679C>T p.P1227S | Missense Mutation (SNP) | VAF 177/381 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs770265120; called by muse, mutect2, varscan2
- TTN | c.95680G>A p.E31894K (on ENST00000591111; = p.E24470K on NM_003319.4) | Missense Mutation (SNP) | VAF 204/300 reads (68%) | PolyPhen probably damaging (0.99); catalogued as COSV60403110; called by muse, mutect2, varscan2
- TTN | c.22436G>A p.R7479Q (on ENST00000591111; = p.R6552Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/270 reads (16%) | PolyPhen benign (0.293); catalogued as rs267599059; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VCAN | c.8365G>A p.D2789N | Missense Mutation (SNP) | VAF 203/213 reads (95%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV54116855; called by muse, mutect2, varscan2
- VRTN | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 234/493 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1013823696, COSV56441664, COSV56442010; called by muse, mutect2, varscan2
- VSIG1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 255/440 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259706; called by muse, mutect2, varscan2
- VWDE | c.4366G>A p.A1456T | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1008021885; called by muse, mutect2, varscan2
- WDR19 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as rs767727756, COSV99975680; called by muse, mutect2, varscan2
- XDH | c.3350G>A p.W1117* | Nonsense Mutation (SNP) | VAF 59/280 reads (21%) | catalogued as COSV65150963; called by muse, mutect2, varscan2
- XIAP | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 164/277 reads (59%) | catalogued as COSV63024598; called by muse, mutect2, varscan2
- ZNF182 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 241/397 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59357456; called by muse, mutect2, varscan2
- ZNF208 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 215/381 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV101236900; called by muse, mutect2, varscan2
- ZNF276 | c.316C>T p.P106S (on ENST00000443381 / NM_001113525.2; = p.P31S on NM_152287.4) | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.138); catalogued as rs202152544; called by muse, mutect2, varscan2
- ZNF443 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.394); catalogued as rs1231548684; called by muse, mutect2, varscan2
- ZNF703 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 312/726 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV58998220; called by muse, mutect2, varscan2
- ZNF786 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 236/480 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs747892425, COSV60274793, COSV60277911; called by muse, mutect2, varscan2
- ZNF99 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV68055691; called by muse, mutect2, varscan2
- ZSCAN20 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 91/432 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63681398; called by muse, mutect2, varscan2
- ABCA6 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 138/154 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ACAN | c.7504G>A p.D2502N (on ENST00000560601 / NM_001369268.1; = p.D2464N on NM_013227.3) | Missense Mutation (SNP) | VAF 86/490 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, varscan2
- ACSM2A | c.761C>T p.S254F (on ENST00000219054; = p.S175F on NM_001308169.2) | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ACSS3 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ADAM20 | c.701T>A p.V234E | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADAM28 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 128/251 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL2 | c.2744G>A p.G915E (on ENST00000370717 / NM_001366005.1; = p.G902E on NM_012302.4) | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADGRL3 | c.4660G>A p.G1554R (on ENST00000506720 / NM_001322402.2; = p.G1443R on NM_015236.6) | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL4 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 119/171 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AEBP1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 136/272 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AGO1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 290/399 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- AGO2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 242/498 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ANKRD50 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 92/250 reads (37%) | called by muse, mutect2, varscan2
- APLF | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 109/161 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- APOB | c.7798T>C p.F2600L | Missense Mutation (SNP) | VAF 178/268 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- APOB | c.5216C>T p.S1739L | Missense Mutation (SNP) | VAF 241/357 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- AQR | c.2398A>G p.I800V | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0.03); called by muse, varscan2
- ARHGAP15 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ARHGAP25 | c.791A>T p.N264I (on ENST00000409202 / NM_001007231.3; = p.N256I on NM_014882.3) | Missense Mutation (SNP) | VAF 178/248 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ARHGEF5 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by mutect2, varscan2
- ARSJ | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATF6B | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 230/530 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- BAZ1A | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- BEND2 | c.1247A>C p.Q416P | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BEND4 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- BLNK | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 177/189 reads (94%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BSN | c.11527A>T p.N3843Y | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, mutect2
- C13orf42 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C14orf180 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 236/528 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- C2orf16 | c.4885G>A p.G1629S | Missense Mutation (SNP) | VAF 281/415 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C8A | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 229/332 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CACNA1E | c.6108A>T p.E2036D (on ENST00000367573 / NM_001205293.3; = p.E1993D on NM_000721.4) | Missense Mutation (SNP) | VAF 312/451 reads (69%) | SIFT tolerated (0.85); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CARMIL2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 63/229 reads (28%) | called by muse, mutect2, varscan2
- CCDC197 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCNE1 | c.1078A>C p.I360L | Missense Mutation (SNP) | VAF 193/344 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC42 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 176/238 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CENPE | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CENPP | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 113/127 reads (89%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CES5A | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHGB | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 162/378 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.208); called by muse, varscan2
- CHRD | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 142/230 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); called by muse, varscan2
- CHST7 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 323/516 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLEC4C | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 118/132 reads (89%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CLIP1 | c.2935A>C p.I979L (on ENST00000620786 / NM_001247997.1; = p.I968L on NM_002956.2) | Missense Mutation (SNP) | VAF 202/215 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2
- COL11A1 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, varscan2
- COL23A1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 227/244 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- COL4A4 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 187/246 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A3 | c.7093G>A p.G2365S | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.4591G>A p.G1531R | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CORO7 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 110/405 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CRAMP1 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 249/388 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CRISPLD1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRLF2 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 193/362 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CRYBG2 | c.4870T>C p.F1624L | Missense Mutation (SNP) | VAF 263/371 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CRYBG3 | c.5557C>T p.R1853C | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.3133G>A p.E1045K (on ENST00000297405 / NM_001363185.1; = p.E941K on NM_052900.3) | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CTAGE15 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- CXorf66 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 204/314 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CYP1B1 | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 110/365 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DAOA | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 202/319 reads (63%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DCAF1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 133/390 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- DCAF8L2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 258/429 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DDRGK1 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 149/338 reads (44%) | called by muse, mutect2, varscan2
- DENND2C | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 136/201 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DEPDC1 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DEUP1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 87/108 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DGKK | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.444); called by muse, varscan2
- DIAPH2 | c.1888A>T p.K630* | Nonsense Mutation (SNP) | VAF 146/248 reads (59%) | called by muse, mutect2, varscan2
- DMXL1 | c.7804G>A p.E2602K | Missense Mutation (SNP) | VAF 81/86 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- DNAH14 | c.8338G>A p.E2780K (on ENST00000445597; = p.E3583K on NM_001367479.1) | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.12748C>T p.Q4250* | Nonsense Mutation (SNP) | VAF 174/195 reads (89%) | called by muse, mutect2, varscan2
- DNAH6 | c.11624T>A p.M3875K | Missense Mutation (SNP) | VAF 179/264 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC5B | c.373T>G p.F125V | Missense Mutation (SNP) | VAF 84/401 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DOK4 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUXA | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DYNC1LI1 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- EPHA10 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 111/562 reads (20%) | called by muse, mutect2, varscan2
- EPS8L3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 246/350 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ERG | c.835G>A p.A279T (on ENST00000398919 / NM_001243428.1; = p.A255T on NM_004449.4) | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ERICH2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYS | c.5753G>A p.G1918E | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171A1 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 152/270 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.136); called by muse, varscan2
- FAM177A1 | c.298T>G p.W100G (on ENST00000382406 / NM_001289022.2; = p.W123G on NM_173607.5) | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- FAM47C | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 256/460 reads (56%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FGB | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FRMD4A | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 252/433 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FRMPD3 | c.3383A>G p.Q1128R | Missense Mutation (SNP) | VAF 296/489 reads (61%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD3 | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 323/560 reads (58%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FRMPD3 | c.4339C>A p.P1447T | Missense Mutation (SNP) | VAF 231/399 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FRMPD4 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 311/484 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- FSIP1 | c.1509T>A p.N503K | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GFI1 | c.872A>T p.K291M | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GLRA2 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GOLIM4 | c.1052T>A p.V351D | Missense Mutation (SNP) | VAF 235/406 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GP1BA | c.1298_1328del p.S433Tfs*29 | Frame Shift Del (DEL) | VAF 123/203 reads (61%) | called by muse*, mutect2, varscan2*
- GPR176 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC6A | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 206/401 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2
- GRIA1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 186/200 reads (93%) | SIFT tolerated (0.42); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GRIK4 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 132/172 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HNF4A | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HSF5 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- HTR3A | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.113); called by muse, mutect2
- IGHG1 | c.1G>A p.A1T | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- IGKV3D-11 | c.303A>T p.E101D | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- IGKV3D-11 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INO80D | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 101/488 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS6L | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA4 | c.2729G>A p.G910E | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ITIH6 | c.2857A>C p.T953P | Missense Mutation (SNP) | VAF 155/435 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- JHY | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 200/246 reads (81%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- KALRN | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 150/266 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNAB1 | c.1055G>A p.G352E (on ENST00000490337 / NM_172160.3; = p.G341E on NM_003471.3) | Missense Mutation (SNP) | VAF 145/264 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIAA1217 | c.811A>C p.N271H | Missense Mutation (SNP) | VAF 142/150 reads (95%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA1217 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 193/213 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL31 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 150/349 reads (43%) | called by muse, mutect2, varscan2
- KMT2C | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- KRT36 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 256/278 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- L1CAM | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDHC | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- LONRF2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- MAGEE2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 118/372 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- MAGI2 | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MANSC1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 207/220 reads (94%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAT2A | c.702A>T p.K234N | Missense Mutation (SNP) | VAF 229/336 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBD5 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 229/321 reads (71%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDGA2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 178/383 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MGAM | c.648A>T p.Q216H | Missense Mutation (SNP) | VAF 73/396 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP7 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MON2 | c.3803C>T p.P1268L | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MSH5 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MTMR10 | c.1729A>G p.K577E | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- MUC12 | c.6277C>T p.P2093S (on ENST00000379442; = p.P1950S on NM_001164462.1) | Missense Mutation (SNP) | VAF 132/1907 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MUC12 | c.15416G>A p.G5139E (on ENST00000379442; = p.G4996E on NM_001164462.1) | Missense Mutation (SNP) | VAF 114/337 reads (34%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC4 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 186/494 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MXRA5 | c.6831G>A p.W2277* | Nonsense Mutation (SNP) | VAF 283/476 reads (59%) | called by muse, mutect2, varscan2
- MYH1 | c.1787G>A p.W596* | Nonsense Mutation (SNP) | VAF 103/210 reads (49%) | called by muse, mutect2, varscan2
- MYH13 | c.1900T>A p.S634T | Missense Mutation (SNP) | VAF 92/103 reads (89%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYH2 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 165/184 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH6 | c.4310C>T p.S1437F | Missense Mutation (SNP) | VAF 231/478 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MYO7A | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- MYO9B | c.6299C>T p.P2100L | Missense Mutation (SNP) | VAF 350/581 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOF | c.3644T>G p.L1215R | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYPOP | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 171/273 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP2L2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 159/242 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCEH1 | c.967A>G p.R323G (on ENST00000538775; = p.R283G on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/332 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- NEFL | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 236/493 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NEXMIF | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 102/333 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- NFASC | c.1322G>A p.R441Q (on ENST00000339876 / NM_001378329.1; = p.R452Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NFATC1 | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 213/359 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NFATC1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 214/361 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NHSL2 | c.19G>A p.V7M (on ENST00000510661; = p.V373M on NM_001013627.2) | Missense Mutation (SNP) | VAF 151/257 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NKD2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 186/203 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP11 | c.2178G>A p.M726I | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NPHS1 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR1I3 | c.868G>A p.E290K (on ENST00000367982 / NM_001077480.3; = p.E286K on NM_005122.5) | Missense Mutation (SNP) | VAF 311/464 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NRK | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- NSUN7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NUB1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 90/207 reads (43%) | called by muse, mutect2, varscan2
- OASL | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 173/198 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- OR11H2 | c.23C>T p.S8F (on ENST00000556246; = p.S19F on NM_001197287.1) | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4F17 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- OR4F21 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR5M3 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 192/253 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PAPLN | c.3721C>G p.L1241V (on ENST00000554301; = p.L1214V on NM_173462.4) | Missense Mutation (SNP) | VAF 199/457 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCCA | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.592); called by muse, mutect2
- PCSK6 | c.1615T>G p.L539V | Missense Mutation (SNP) | VAF 180/765 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- PDCD2L | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PDE1C | c.100C>T p.L34= | Splice Region (SNP) | VAF 80/182 reads (44%) | called by muse, mutect2, varscan2
- PEX1 | c.1196A>T p.K399I | Missense Mutation (SNP) | VAF 132/244 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, varscan2
- PIK3R6 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 185/204 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PKHD1 | c.9628T>G p.S3210A | Missense Mutation (SNP) | VAF 183/404 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PKHD1L1 | c.8924G>A p.G2975E | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PLCE1 | c.2723T>A p.L908H | Missense Mutation (SNP) | VAF 217/234 reads (93%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PLCL2 | c.433G>A p.E145K (on ENST00000615277 / NM_001144382.2; = p.E19K on NM_015184.5) | Missense Mutation (SNP) | VAF 185/316 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- PLEKHG2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PMIS2 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 130/330 reads (39%) | called by muse, varscan2
- PON1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PON3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 208/417 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PPL | c.3041G>T p.R1014L | Missense Mutation (SNP) | VAF 110/410 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by mutect2, varscan2
- PPP1R3A | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 199/396 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PRAMEF11 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 56/516 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.088); called by muse, varscan2
- PRDM1 | c.1776C>T p.V592= | Splice Region (SNP) | VAF 115/241 reads (48%) | called by muse, mutect2, varscan2
- PRDM13 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 283/624 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PRKCB | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 149/228 reads (65%) | called by muse, mutect2, varscan2
- PRR23A | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 271/462 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRRG3 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 318/528 reads (60%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRUNE2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 152/168 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PSG5 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 139/241 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PTCHD3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 189/209 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PTPRQ | c.3026T>A p.L1009H (on ENST00000616559; = p.L967H on NM_001145026.2) | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PXDNL | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RAB11FIP5 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 354/547 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAD23A | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 130/196 reads (66%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBBP5 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- RBBP8NL | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 259/561 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RBBP8NL | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 162/351 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBMXL2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- RFX6 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 139/322 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RGCC | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- RNF112 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 273/307 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RNF13 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 109/188 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RNF148 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 198/439 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROBO1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RP1 | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 168/339 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, varscan2
- RPGR | c.2879C>T p.P960L (on ENST00000339363 / NM_001367249.1; = p.P755L on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RUNX2 | c.1144C>T p.L382F (on ENST00000371438; = p.L360F on NM_001015051.3) | Missense Mutation (SNP) | VAF 196/414 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- RUNX3 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 416/570 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RYR1 | c.10686G>A p.K3562= | Splice Region (SNP) | VAF 112/203 reads (55%) | called by muse, mutect2, varscan2
- SALL4 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 248/499 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SCIN | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN10A | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 101/156 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SCN7A | c.2840G>A p.S947N | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SCN8A | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SERPINB12 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 127/247 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB3 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SETBP1 | c.1003A>T p.K335* | Nonsense Mutation (SNP) | VAF 171/254 reads (67%) | called by muse, mutect2, varscan2
- SETD2 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SFXN5 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 150/281 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SGMS1 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 160/178 reads (90%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SIRPG | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- SLAMF9 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- SLC17A8 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 222/250 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SLC25A3 | c.991T>C p.F331L (on ENST00000228318 / NM_005888.3; = p.F330L on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/188 reads (93%) | SIFT tolerated (0.42); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SLC35F4 | c.1294G>A p.G432R (on ENST00000339762 / NM_001352015.2; = p.G396R on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A4 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLC6A11 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC9A2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9C1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 210/384 reads (55%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLCO6A1 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 96/101 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SMS | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 141/236 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMTNL1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- SOBP | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 257/547 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SORCS2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, varscan2
- SP1 | c.704C>T p.A235V (on ENST00000327443 / NM_138473.3; = p.A228V on NM_003109.1) | Missense Mutation (SNP) | VAF 224/247 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ST18 | c.890A>C p.E297A | Missense Mutation (SNP) | VAF 229/461 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- STK26 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- SUCLA2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 175/265 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- TBX22 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 108/282 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEAL7 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 182/317 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TDRD1 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 87/94 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD7 | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TEX13C | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT tolerated (0.62); called by muse, mutect2, varscan2
- TEX2 | c.2708C>T p.S903F (on ENST00000583097 / NM_001288733.2; = p.S910F on NM_018469.5) | Missense Mutation (SNP) | VAF 116/138 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- THSD7B | c.925A>C p.S309R | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR3 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TMEM132C | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 172/195 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TMEM132C | c.1900G>T p.G634W | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM164 | c.789G>T p.M263I (on ENST00000372068 / NM_032227.4; = p.M114I on NM_017698.2) | Missense Mutation (SNP) | VAF 138/506 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM184A | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 270/515 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, varscan2
- TMSB15A | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRABD2B | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 137/681 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRANK1 | c.6447G>A p.M2149I | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRERF1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 289/617 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM3 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 317/371 reads (85%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRMT2B | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 186/300 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPC6 | c.2348G>A p.W783* | Nonsense Mutation (SNP) | VAF 150/189 reads (79%) | called by muse, mutect2, varscan2
- TTYH1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 167/291 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBA3C | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- UGT1A8 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UGT2B11 | c.1090+1G>A p.X364_splice | Splice Site (SNP) | VAF 101/187 reads (54%) | called by muse, mutect2, varscan2
- UHRF1 | c.976G>A p.D326N (on ENST00000612630 / NM_001290050.1; = p.D339N on NM_013282.4) | Missense Mutation (SNP) | VAF 235/381 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- UPF3B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 266/448 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- URGCP | c.870G>A p.W290* (on ENST00000453200 / NM_001077663.3; = p.W281* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 181/450 reads (40%) | called by muse, mutect2, varscan2
- USP34 | c.5829G>T p.M1943I | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, varscan2
- USP6 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 131/169 reads (78%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- VCX3B | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR83OS | c.242T>C p.M81T | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- WDR87 | c.6474A>C p.E2158D | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by mutect2, varscan2
- WNK1 | c.5251C>T p.P1751S (on ENST00000315939 / NM_018979.4; = p.P1504S on NM_014823.3) | Missense Mutation (SNP) | VAF 108/120 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WNK2 | c.4141C>T p.P1381S | Missense Mutation (SNP) | VAF 107/123 reads (87%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIAP | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- XKR6 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 181/426 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZC3H4 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 261/433 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF189 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 182/200 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ZNF253 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 128/219 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF449 | c.522T>A p.Y174* | Nonsense Mutation (SNP) | VAF 198/324 reads (61%) | called by muse, mutect2, varscan2
- ZNF479 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ZNF496 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF549 | c.547C>T p.P183S (on ENST00000376233 / NM_001199295.2; = p.P170S on NM_153263.2) | Missense Mutation (SNP) | VAF 197/337 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF618 | c.2428C>T p.P810S (on ENST00000374126 / NM_001318042.2; = p.P717S on NM_133374.2) | Missense Mutation (SNP) | VAF 231/249 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF660 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM2 | c.1492C>T p.Q498* | Nonsense Mutation (SNP) | VAF 116/182 reads (64%) | called by muse, mutect2, varscan2
- ABCB9 | c.1671C>T p.P557= (on ENST00000280560 / NM_019625.4; = p.P514= on NM_019624.3) | Silent (SNP) | VAF 275/298 reads (92%) | catalogued as rs181063039; called by muse, mutect2, varscan2
- ACSM1 | c.1077G>A p.T359= | Silent (SNP) | VAF 86/309 reads (28%) | catalogued as rs141054663; called by muse, mutect2, varscan2
- ADCY4 | c.2391C>T p.F797= | Silent (SNP) | VAF 230/435 reads (53%) | catalogued as rs770166725, COSV60257506; called by muse, mutect2, varscan2
- ADGRE1 | c.1572G>A p.K524= | Silent (SNP) | VAF 66/206 reads (32%) | called by muse, mutect2, varscan2
- ADGRF5 | c.2856G>A p.T952= | Silent (SNP) | VAF 175/383 reads (46%) | catalogued as rs768306801, COSV51932529; called by muse, mutect2, varscan2
- ADH1A | c.273C>T p.I91= | Silent (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- AGAP1 | c.1563C>T p.S521= (on ENST00000304032 / NM_001037131.3; = p.S468= on NM_014914.5) | Silent (SNP) | VAF 344/423 reads (81%) | called by muse, mutect2, varscan2
- AGPAT4 | c.33C>T p.F11= | Silent (SNP) | VAF 117/295 reads (40%) | called by muse, mutect2, varscan2
- AGPS | c.987C>T p.I329= | Silent (SNP) | VAF 94/150 reads (63%) | catalogued as rs141468906; called by muse, mutect2, varscan2
- AGRN | c.4429C>T p.L1477= | Silent (SNP) | VAF 122/560 reads (22%) | called by muse, mutect2, varscan2
- ALPK2 | c.2928C>T p.A976= | Silent (SNP) | VAF 72/256 reads (28%) | called by muse, mutect2, varscan2
- AP3B2 | c.1425G>A p.Q475= | Silent (SNP) | VAF 75/387 reads (19%) | catalogued as COSV55613036; called by muse, mutect2, varscan2
- APOB | c.3297G>A p.K1099= | Silent (SNP) | VAF 100/398 reads (25%) | catalogued as COSV51926733; called by muse, mutect2, varscan2
- APOBEC3D | c.324C>T p.P108= | Silent (SNP) | VAF 230/624 reads (37%) | catalogued as rs1349097271, COSV53328015; called by muse, mutect2, varscan2
- ARHGAP17 | c.861C>T p.F287= | Silent (SNP) | VAF 127/228 reads (56%) | catalogued as rs199859003; called by muse, mutect2, varscan2
- ARMC9 | c.1518C>T p.V506= | Silent (SNP) | VAF 63/305 reads (21%) | called by muse, mutect2, varscan2
- ASPHD1 | c.411G>A p.G137= | Silent (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- ASPHD2 | c.963C>T p.L321= | Silent (SNP) | VAF 285/476 reads (60%) | catalogued as COSV53218575; called by muse, mutect2, varscan2
- ATIC | c.1552T>C p.L518= | Silent (SNP) | VAF 105/363 reads (29%) | called by muse, mutect2, varscan2
- BMP15 | c.117C>T p.A39= | Silent (SNP) | VAF 297/513 reads (58%) | called by muse, mutect2, varscan2
- BRINP2 | c.1167C>T p.I389= | Silent (SNP) | VAF 76/405 reads (19%) | catalogued as rs1017297077, COSV64177580, COSV64178388; called by muse, mutect2, varscan2
- C10orf71 | c.1938C>T p.S646= | Silent (SNP) | VAF 155/172 reads (90%) | catalogued as rs1317925278; called by muse, mutect2, varscan2
- C13orf42 | c.369G>A p.K123= | Silent (SNP) | VAF 59/288 reads (20%) | called by muse, mutect2, varscan2
- C1orf158 | c.471G>A p.L157= | Silent (SNP) | VAF 279/421 reads (66%) | catalogued as COSV99847275; called by muse, mutect2, varscan2
- C2orf16 | c.2109G>A p.V703= | Silent (SNP) | VAF 96/396 reads (24%) | called by muse, mutect2, varscan2
- C2orf16 | c.4884G>A p.R1628= | Silent (SNP) | VAF 285/419 reads (68%) | called by muse, mutect2, varscan2
- C7orf33 | c.351G>A p.R117= | Silent (SNP) | VAF 204/426 reads (48%) | called by muse, mutect2, varscan2
- CACNA1B | c.5733C>T p.F1911= | Silent (SNP) | VAF 224/239 reads (94%) | catalogued as COSV53120107; called by muse, mutect2, varscan2
- CACNA2D1 | c.906C>T p.S302= | Silent (SNP) | VAF 94/203 reads (46%) | catalogued as rs749519172, COSV100667336; called by muse, mutect2, varscan2
- CALN1 | c.567C>T p.V189= (on ENST00000329008 / NM_001017440.3; = p.V231= on NM_031468.4) | Silent (SNP) | VAF 156/301 reads (52%) | called by muse, mutect2, varscan2
- CASD1 | c.264T>C p.I88= | Silent (SNP) | VAF 63/165 reads (38%) | called by muse, mutect2, varscan2
- CASKIN1 | c.2769C>T p.P923= | Silent (SNP) | VAF 129/489 reads (26%) | catalogued as rs1226520893, COSV58218022; called by muse, mutect2, varscan2
- CBLC | c.1038C>T p.S346= | Silent (SNP) | VAF 106/284 reads (37%) | called by muse, mutect2, varscan2
- CCDC168 | c.17205G>A p.R5735= | Silent (SNP) | VAF 83/277 reads (30%) | called by muse, mutect2, varscan2
- CCDC168 | c.2397G>A p.K799= | Silent (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2, varscan2
- CCDC196 | c.327G>A p.K109= | Silent (SNP) | VAF 158/328 reads (48%) | called by muse, mutect2, varscan2
- CCNB3 | c.1137C>T p.I379= | Silent (SNP) | VAF 218/368 reads (59%) | called by muse, varscan2
- CDKN2A | c.243C>T p.P81= | Silent (SNP) | VAF 331/372 reads (89%) | catalogued as rs1060504185, CD951647, COSV58688708; ClinVar: uncertain significance; called by mutect2, varscan2
- CDS2 | c.1053C>T p.P351= | Silent (SNP) | VAF 157/368 reads (43%) | catalogued as rs747821960; called by muse, mutect2, varscan2
- CEP162 | c.447G>A p.S149= | Silent (SNP) | VAF 106/253 reads (42%) | catalogued as rs149716513; called by muse, mutect2, varscan2
- CES5A | c.1374C>T p.V458= | Silent (SNP) | VAF 110/433 reads (25%) | catalogued as rs751110837; called by muse, mutect2
- CFHR5 | c.1683G>A p.G561= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as COSV56829469; called by muse, mutect2, varscan2
- CGREF1 | c.591C>T p.A197= | Silent (SNP) | VAF 367/532 reads (69%) | catalogued as rs1345387018; called by muse, mutect2, varscan2
- CHRNA7 | c.729C>T p.L243= | Silent (SNP) | VAF 110/360 reads (31%) | called by muse, mutect2, varscan2
- CIITA | c.1377G>A p.P459= | Silent (SNP) | VAF 114/374 reads (30%) | catalogued as rs749946306, COSV60855989; called by muse, mutect2, varscan2
- CLASRP | c.1287C>T p.S429= | Silent (SNP) | VAF 208/613 reads (34%) | catalogued as rs937635640; called by muse, mutect2, varscan2
- CNTNAP4 | c.2898G>A p.G966= | Silent (SNP) | VAF 72/278 reads (26%) | catalogued as rs371905330; called by muse, mutect2, varscan2
- COL11A1 | c.4923C>T p.F1641= | Silent (SNP) | VAF 45/289 reads (16%) | catalogued as COSV62174939; called by muse, mutect2, varscan2
- COL11A1 | c.4851C>T p.F1617= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV62173713; called by muse, mutect2, varscan2
- COL23A1 | c.744A>T p.T248= | Silent (SNP) | VAF 227/244 reads (93%) | called by muse, mutect2, varscan2
- COL6A2 | c.60C>T p.A20= | Silent (SNP) | VAF 93/325 reads (29%) | called by muse, mutect2, varscan2
- COL8A1 | c.960G>A p.Q320= | Silent (SNP) | VAF 231/382 reads (60%) | catalogued as COSV53741241; called by muse, mutect2, varscan2
- CPZ | c.999C>T p.Y333= (on ENST00000360986 / NM_001014447.3; = p.Y322= on NM_003652.3) | Silent (SNP) | VAF 111/295 reads (38%) | catalogued as rs149008174; called by muse, mutect2, varscan2
- CSMD1 | c.9165C>T p.T3055= (on ENST00000520002; = p.T3054= on NM_033225.6) | Silent (SNP) | VAF 189/407 reads (46%) | catalogued as rs773425697; called by muse, mutect2, varscan2
- CTAGE4 | c.2163C>T p.F721= | Silent (SNP) | VAF 126/1346 reads (9%) | catalogued as rs750363066; called by muse, varscan2
- CTNNA3 | c.141G>A p.R47= | Silent (SNP) | VAF 125/136 reads (92%) | catalogued as rs868542587, COSV57717087; called by muse, mutect2, varscan2
- CYP4A22 | c.927G>A p.K309= | Silent (SNP) | VAF 216/521 reads (41%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.1572G>A p.V524= | Silent (SNP) | VAF 234/386 reads (61%) | called by muse, mutect2, varscan2
- DCSTAMP | c.876C>T p.N292= | Silent (SNP) | VAF 185/404 reads (46%) | catalogued as rs1354858026; called by muse, mutect2, varscan2
- DENND2C | c.2205C>T p.I735= (on ENST00000393274 / NM_001256404.2; = p.I678= on NM_198459.4) | Silent (SNP) | VAF 67/328 reads (20%) | catalogued as rs762792966, COSV101283960; called by muse, mutect2, varscan2
- DGAT2L6 | c.231C>T p.T77= | Silent (SNP) | VAF 122/357 reads (34%) | catalogued as COSV100284021; called by muse, mutect2, varscan2
- DNAAF5 | c.972G>T p.L324= | Silent (SNP) | VAF 146/298 reads (49%) | called by muse, mutect2, varscan2
- DNAH10 | c.4416C>T p.F1472= (on ENST00000409039; = p.F1411= on NM_207437.3) | Silent (SNP) | VAF 186/200 reads (93%) | called by muse, mutect2, varscan2
- DNAH8 | c.5887C>T p.L1963= | Silent (SNP) | VAF 134/330 reads (41%) | called by muse, mutect2, varscan2
- DNAJB14 | c.90C>T p.F30= | Silent (SNP) | VAF 121/323 reads (37%) | catalogued as rs1454795126, COSV56455322; called by muse, mutect2, varscan2
- DSC1 | c.996C>T p.F332= | Silent (SNP) | VAF 63/259 reads (24%) | catalogued as rs371108741, COSV57146138; called by muse, mutect2, varscan2
- DSCAM | c.1083G>A p.R361= | Silent (SNP) | VAF 126/380 reads (33%) | catalogued as COSV68037553; called by muse, mutect2, varscan2
- EEPD1 | c.100C>T p.L34= | Silent (SNP) | VAF 201/476 reads (42%) | called by muse, mutect2, varscan2
- ENPEP | c.357G>A p.V119= | Silent (SNP) | VAF 178/368 reads (48%) | catalogued as COSV54455914; called by muse, mutect2, varscan2
- ERBB4 | c.2295C>T p.F765= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- ESR2 | c.966C>T p.L322= | Silent (SNP) | VAF 160/311 reads (51%) | catalogued as rs1338751185; called by muse, mutect2, varscan2
- F10 | c.354C>G p.G118= | Silent (SNP) | VAF 161/249 reads (65%) | called by muse, mutect2, varscan2
- FAM155A | c.324G>A p.A108= | Silent (SNP) | VAF 452/640 reads (71%) | called by muse, varscan2
- FAM160B2 | c.783C>T p.A261= | Silent (SNP) | VAF 168/354 reads (47%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1170G>A p.T390= | Silent (SNP) | VAF 102/298 reads (34%) | catalogued as rs771844084, COSV65313645; called by muse, varscan2
- FAT1 | c.2922C>T p.F974= | Silent (SNP) | VAF 77/223 reads (35%) | catalogued as rs773046409; called by muse, mutect2, varscan2
- FER1L5 | c.5478G>A p.A1826= (on ENST00000623019; = p.A1790= on NM_001293083.2) | Silent (SNP) | VAF 68/320 reads (21%) | catalogued as rs778242448, COSV53841828; called by muse, mutect2, varscan2
- FREM2 | c.5457G>A p.K1819= | Silent (SNP) | VAF 84/334 reads (25%) | catalogued as rs1470666927; called by muse, mutect2, varscan2
- FRMPD4 | c.3618C>T p.G1206= | Silent (SNP) | VAF 99/410 reads (24%) | called by muse, mutect2, varscan2
- FUT9 | c.1062G>A p.E354= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV56145790; called by muse, mutect2, varscan2
- G6PD | c.18C>T p.A6= | Silent (SNP) | VAF 99/322 reads (31%) | catalogued as COSV99682420; called by muse, mutect2, varscan2
- GABRD | c.960C>T p.F320= | Silent (SNP) | VAF 105/493 reads (21%) | catalogued as rs201101812, COSV66081156; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAL3ST1 | c.510C>T p.F170= | Silent (SNP) | VAF 281/721 reads (39%) | catalogued as rs769714165, COSV58891970, COSV58893380; called by muse, mutect2, varscan2
- GALNT15 | c.960C>T p.F320= | Silent (SNP) | VAF 107/320 reads (33%) | called by muse, mutect2, varscan2
- GC | c.447G>A p.R149= | Silent (SNP) | VAF 74/149 reads (50%) | called by muse, mutect2, varscan2
- GGT6 | c.525C>T p.P175= (on ENST00000574154 / NM_001122890.3; = p.P143= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 291/323 reads (90%) | catalogued as rs749181550, COSV99625549; called by muse, mutect2, varscan2
- GIMAP7 | c.33C>T p.I11= | Silent (SNP) | VAF 117/275 reads (43%) | catalogued as rs142236871, COSV57959703; called by muse, mutect2, varscan2
- GLI2 | c.2686C>T p.L896= (on ENST00000361492 / NM_001374353.1; = p.L913= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 145/630 reads (23%) | catalogued as rs867102600; called by muse, mutect2, varscan2
- GPR18 | c.378G>A p.P126= | Silent (SNP) | VAF 210/315 reads (67%) | catalogued as rs1398899115; called by muse, mutect2, varscan2
- GPR20 | c.687C>T p.L229= | Silent (SNP) | VAF 346/705 reads (49%) | called by muse, mutect2
- GRID2 | c.1110G>A p.L370= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as rs191438581; called by muse, mutect2, varscan2
- GRIN1 | c.333C>A p.A111= | Silent (SNP) | VAF 94/424 reads (22%) | called by muse, mutect2, varscan2
- GRIN3A | c.870C>T p.H290= | Silent (SNP) | VAF 178/197 reads (90%) | called by muse, mutect2, varscan2
- GRM3 | c.732G>A p.A244= | Silent (SNP) | VAF 192/436 reads (44%) | catalogued as COSV64475772; called by muse, mutect2, varscan2
- GSAP | c.594C>T p.G198= | Silent (SNP) | VAF 75/148 reads (51%) | catalogued as rs769555317; called by muse, mutect2, varscan2
- GYPA | c.213C>T p.Y71= | Silent (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- H3C2 | c.366C>T p.P122= | Silent (SNP) | VAF 146/327 reads (45%) | called by muse, mutect2, varscan2
- HBG2 | c.213C>T p.S71= | Silent (SNP) | VAF 214/508 reads (42%) | called by muse, varscan2
- HDGFL1 | c.297G>A p.K99= | Silent (SNP) | VAF 267/611 reads (44%) | called by muse, mutect2, varscan2
- HGD | c.666C>T p.A222= | Silent (SNP) | VAF 87/246 reads (35%) | called by muse, mutect2, varscan2
- HIGD1A | c.105G>A p.A35= | Silent (SNP) | VAF 124/217 reads (57%) | catalogued as rs544533473; called by muse, mutect2, varscan2
- HS6ST2 | c.645C>T p.L215= | Silent (SNP) | VAF 291/492 reads (59%) | catalogued as rs770199205; called by muse, mutect2, varscan2
- IGHD2-15 | c.1A>C p.R1= | Silent (SNP) | VAF 76/317 reads (24%) | catalogued as rs1555394864; called by muse, mutect2, varscan2
- INPP5D | c.1416C>T p.I472= (on ENST00000445964 / NM_001017915.3; = p.I471= on NM_005541.5) | Silent (SNP) | VAF 197/311 reads (63%) | catalogued as rs994109046; called by muse, mutect2, varscan2
- IQSEC3 | c.363G>A p.L121= | Silent (SNP) | VAF 245/568 reads (43%) | catalogued as rs782718236, COSV100407650; called by muse, mutect2, varscan2
- ITIH4 | c.2175C>T p.T725= | Silent (SNP) | VAF 213/388 reads (55%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.615C>T p.F205= | Silent (SNP) | VAF 76/168 reads (45%) | called by muse, mutect2, varscan2
- KALRN | c.8574C>T p.S2858= (on ENST00000360013 / NM_001024660.4; = p.S1161= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/406 reads (33%) | called by muse, mutect2, varscan2
- KCNA3 | c.1635C>T p.T545= | Silent (SNP) | VAF 335/440 reads (76%) | called by muse, mutect2, varscan2
- KDM2A | c.2949C>T p.L983= | Silent (SNP) | VAF 129/166 reads (78%) | catalogued as COSV100445796; called by muse, mutect2, varscan2
- KHDRBS2 | c.261C>T p.S87= | Silent (SNP) | VAF 166/339 reads (49%) | catalogued as rs1305550996, COSV55432877; called by muse, mutect2, varscan2
- KIAA1109 | c.2802C>T p.C934= | Silent (SNP) | VAF 50/165 reads (30%) | called by muse, mutect2, varscan2
- KL | c.1257C>T p.V419= | Silent (SNP) | VAF 104/260 reads (40%) | called by muse, mutect2, varscan2
- KL | c.1809C>T p.L603= | Silent (SNP) | VAF 102/465 reads (22%) | catalogued as rs777479302, COSV66309506; called by muse, mutect2, varscan2
- KLK3 | c.216G>A p.V72= | Silent (SNP) | VAF 85/143 reads (59%) | catalogued as COSV58101320; called by muse, mutect2, varscan2
- KRT37 | c.693G>A p.L231= | Silent (SNP) | VAF 295/326 reads (90%) | catalogued as rs755326771; called by muse, mutect2, varscan2
- KRT73 | c.516G>A p.L172= | Silent (SNP) | VAF 173/190 reads (91%) | catalogued as COSV59841923; called by muse, mutect2, varscan2
- LAMA2 | c.2340A>G p.T780= | Silent (SNP) | VAF 113/239 reads (47%) | called by muse, mutect2, varscan2
- LAYN | c.546C>T p.F182= (on ENST00000375615 / NM_001258390.1; = p.F174= on NM_178834.5) | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- LHCGR | c.1083C>T p.F361= | Silent (SNP) | VAF 80/320 reads (25%) | catalogued as COSV54295946; called by muse, mutect2
- LPIN1 | c.297C>T p.I99= | Silent (SNP) | VAF 122/171 reads (71%) | catalogued as COSV56770702; called by muse, mutect2, varscan2
- LRFN2 | c.1800G>A p.P600= | Silent (SNP) | VAF 243/576 reads (42%) | catalogued as rs749673103; called by muse, mutect2, varscan2
- LRP12 | c.1263C>T p.S421= | Silent (SNP) | VAF 152/336 reads (45%) | catalogued as COSV99408081; called by muse, mutect2, varscan2
- LRRC20 | c.285C>T p.A95= (on ENST00000355790 / NM_207119.3; = p.A45= on NM_018239.4) | Silent (SNP) | VAF 230/250 reads (92%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.4083C>T p.S1361= | Silent (SNP) | VAF 160/177 reads (90%) | called by muse, mutect2, varscan2
- MAGEB6B | c.873C>T p.I291= | Silent (SNP) | VAF 193/337 reads (57%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1356C>T p.P452= | Silent (SNP) | VAF 234/402 reads (58%) | catalogued as COSV53576028; called by muse, mutect2, varscan2
- MON1A | c.1839C>T p.L613= | Silent (SNP) | VAF 88/289 reads (30%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 190/427 reads (44%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MRGPRX1 | c.711C>T p.F237= | Silent (SNP) | VAF 187/400 reads (47%) | catalogued as COSV57106307; called by muse, mutect2, varscan2
- MROH2A | c.2118C>T p.V706= | Silent (SNP) | VAF 207/315 reads (66%) | called by muse, mutect2, varscan2
- MROH2B | c.3102C>T p.V1034= | Silent (SNP) | VAF 153/172 reads (89%) | called by muse, mutect2, varscan2
- MROH2B | c.744C>T p.F248= | Silent (SNP) | VAF 98/108 reads (91%) | catalogued as rs767668471, COSV101270658, COSV68181265, COSV68190391; called by muse, mutect2, varscan2
- MTHFR | c.792C>T p.S264= | Silent (SNP) | VAF 143/206 reads (69%) | catalogued as rs1309422719, COSV64876956; called by muse, mutect2, varscan2
- MTMR1 | c.1599T>C p.L533= | Silent (SNP) | VAF 143/206 reads (69%) | called by muse, mutect2, varscan2
- MTRR | c.939G>A p.T313= (on ENST00000264668; = p.T286= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 145/159 reads (91%) | catalogued as rs762745815; called by muse, mutect2, varscan2
- MUC16 | c.32910G>A p.G10970= | Silent (SNP) | VAF 172/286 reads (60%) | catalogued as rs749426568; called by muse, mutect2, varscan2
- MUC16 | c.7380G>A p.E2460= | Silent (SNP) | VAF 100/338 reads (30%) | called by muse, mutect2, varscan2
- MYH14 | c.828C>T p.I276= | Silent (SNP) | VAF 211/353 reads (60%) | catalogued as rs375516674; called by muse, mutect2, varscan2
- MYO7A | c.1809C>T p.T603= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- MYRFL | c.2148G>A p.R716= | Silent (SNP) | VAF 179/282 reads (63%) | catalogued as rs568619506; called by muse, mutect2, varscan2
- NAA11 | c.306T>C p.F102= | Silent (SNP) | VAF 119/232 reads (51%) | catalogued as rs752354934; called by muse, mutect2, varscan2
- NBPF12 | c.660C>T p.S220= | Silent (SNP) | VAF 262/396 reads (66%) | called by muse, mutect2, varscan2
- NCAPH | c.513C>T p.A171= | Silent (SNP) | VAF 231/353 reads (65%) | catalogued as rs776797054; called by muse, mutect2, varscan2
- NCOA3 | c.891C>T p.I297= | Silent (SNP) | VAF 137/351 reads (39%) | called by muse, mutect2, varscan2
- NCOA4 | c.760C>T p.L254= | Silent (SNP) | VAF 125/145 reads (86%) | called by muse, mutect2, varscan2
- NECTIN2 | c.528C>T p.D176= | Silent (SNP) | VAF 207/397 reads (52%) | called by muse, mutect2, varscan2
- NEDD4L | c.1323C>T p.I441= (on ENST00000400345 / NM_001144967.3; = p.I421= on NM_015277.6) | Silent (SNP) | VAF 83/248 reads (33%) | catalogued as COSV56845090; called by muse, mutect2, varscan2
- NETO1 | c.834C>T p.S278= | Silent (SNP) | VAF 135/227 reads (59%) | catalogued as rs573895946; called by muse, mutect2, varscan2
- NLRP9 | c.1521G>A p.L507= | Silent (SNP) | VAF 127/395 reads (32%) | called by muse, mutect2, varscan2
- NOMO1 | c.2826C>T p.I942= | Silent (SNP) | VAF 133/284 reads (47%) | catalogued as rs765184674; called by muse, mutect2, varscan2
- NQO1 | c.162G>A p.K54= | Silent (SNP) | VAF 89/158 reads (56%) | called by muse, mutect2, varscan2
- NRIP2 | c.336G>A p.K112= | Silent (SNP) | VAF 166/179 reads (93%) | called by muse, mutect2, varscan2
- NRXN3 | c.1854G>A p.G618= (on ENST00000335750 / NM_001330195.2; = p.G245= on NM_004796.6) | Silent (SNP) | VAF 189/472 reads (40%) | called by muse, mutect2, varscan2
- NT5C1B | c.972G>A p.R324= (on ENST00000359846 / NM_001199086.2; = p.R264= on NM_033253.4) | Silent (SNP) | VAF 113/438 reads (26%) | catalogued as rs151116969, COSV58394392; called by muse, mutect2, varscan2
- NTN5 | c.274C>T p.L92= | Silent (SNP) | VAF 173/528 reads (33%) | catalogued as COSV54308767; called by muse, mutect2, varscan2
- NUMBL | c.837C>T p.T279= | Silent (SNP) | VAF 262/463 reads (57%) | called by muse, mutect2, varscan2
- NXPH2 | c.123G>A p.G41= | Silent (SNP) | VAF 258/354 reads (73%) | called by muse, mutect2, varscan2
- NYAP2 | c.501G>A p.G167= | Silent (SNP) | VAF 56/264 reads (21%) | catalogued as COSV56002217; called by muse, mutect2, varscan2
- OR10C1 | c.642C>T p.L214= (on ENST00000622521; = p.L212= on NM_013941.3) | Silent (SNP) | VAF 346/690 reads (50%) | called by muse, mutect2, varscan2
- OR10J3 | c.343C>T p.L115= | Silent (SNP) | VAF 98/416 reads (24%) | catalogued as COSV100171874; called by muse, mutect2, varscan2
- OR10Z1 | c.681G>A p.R227= | Silent (SNP) | VAF 102/447 reads (23%) | called by muse, mutect2, varscan2
- OR11H2 | c.486C>T p.I162= (on ENST00000556246; = p.I173= on NM_001197287.1) | Silent (SNP) | VAF 182/729 reads (25%) | called by muse, mutect2, varscan2
- OR13C2 | c.429C>T p.P143= | Silent (SNP) | VAF 154/172 reads (90%) | called by muse, mutect2, varscan2
- OR2F1 | c.78C>T p.S26= | Silent (SNP) | VAF 193/418 reads (46%) | catalogued as rs771614966, COSV67331426; called by muse, mutect2, varscan2
- OR2G2 | c.627C>T p.F209= | Silent (SNP) | VAF 60/324 reads (19%) | catalogued as rs753840185, COSV60741625; called by muse, mutect2, varscan2
- OR4A47 | c.399C>T p.I133= | Silent (SNP) | VAF 142/176 reads (81%) | called by muse, mutect2
- OR4M1 | c.183C>T p.F61= | Silent (SNP) | VAF 160/602 reads (27%) | catalogued as COSV60060150; called by muse, mutect2, varscan2
- OR51Q1 | c.621C>T p.L207= | Silent (SNP) | VAF 144/177 reads (81%) | called by muse, mutect2, varscan2
- OR52A1 | c.903G>A p.Q301= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- OTOGL | c.6207T>C p.C2069= (on ENST00000547103; = p.C2060= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- OTUD6A | c.186G>A p.E62= | Silent (SNP) | VAF 137/482 reads (28%) | called by muse, mutect2, varscan2
- PADI3 | c.1994G>A p.*665= | Silent (SNP) | VAF 121/175 reads (69%) | catalogued as rs149978330; called by muse, mutect2, varscan2
- PAK6 | c.957C>T p.S319= | Silent (SNP) | VAF 138/303 reads (46%) | called by muse, mutect2, varscan2
- PALLD | c.990C>T p.I330= | Silent (SNP) | VAF 153/321 reads (48%) | called by muse, mutect2, varscan2
- PCDH17 | c.2874C>T p.F958= | Silent (SNP) | VAF 239/325 reads (74%) | catalogued as COSV64977585; called by muse, mutect2, varscan2
- PCDHB12 | c.657C>T p.S219= | Silent (SNP) | VAF 191/207 reads (92%) | catalogued as rs1554286687, COSV99507061; called by muse, mutect2, varscan2
- PDZRN4 | c.3051G>A p.G1017= (on ENST00000402685 / NM_001164595.2; = p.G759= on NM_013377.4) | Silent (SNP) | VAF 151/173 reads (87%) | catalogued as COSV100114191; called by muse, varscan2
131 further variants in this file (0 protein-altering or splice-affecting, 93 silent, 38 other) are not listed here.
